Somatic mutation profile of tumor specimen TCGA-13-1489-01A (aliquot TCGA-13-1489-01A-01W-0549-09) from TCGA case TCGA-13-1489, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 70.5 years (25,768 days).
Specimen TCGA-13-1489-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86451eb0-203d-4937-8dc3-9233638f0c96.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1489-10A (Blood Derived Normal), aliquot TCGA-13-1489-10A-01W-0549-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ff5e4ac-1d30-42db-a491-21e64a6c64ab

The open-access MAF lists 71 somatic variants for this specimen: 58 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 12, Splice Site 5, Frame Shift Del 4, Frame Shift Ins 3, Nonsense Mutation 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 154/168 reads (92%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABI2 | c.613C>G p.R205G (on ENST00000295851 / NM_001375719.1; = p.R199G on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/318 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV53690602, COSV99651806; called by muse, mutect2
- ALG9 | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 82/100 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67645720; called by muse, varscan2
- ANGPT1 | c.857_858insAA p.C286* | Nonsense Mutation (INS) | VAF 17/66 reads (26%) | catalogued as COSV52458892; called by mutect2, pindel*, varscan2
- ANK3 | c.9024C>G p.H3008Q | Missense Mutation (SNP) | VAF 27/29 reads (93%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV55085234; called by muse, mutect2, varscan2
- ATXN3L | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 64/151 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs1037712907, COSV66075382, COSV66076328; called by muse, mutect2, varscan2
- BNIP1 | c.269G>T p.S90I | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV51571476; called by muse, mutect2
- BTK | c.1775C>T p.S592F | Missense Mutation (SNP) | VAF 53/60 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as CM003419, COSV58124175; called by muse, mutect2, varscan2
- C21orf62 | c.180G>T p.M60I | Missense Mutation (SNP) | VAF 126/302 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV66672763; called by muse, mutect2, varscan2
- C2orf16 | c.4905G>C p.Q1635H | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.277); catalogued as COSV62678737; called by muse, mutect2, varscan2
- CACNA1D | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.07); catalogued as COSV55466918; called by muse, mutect2, varscan2
- CD2BP2 | c.862G>C p.E288Q | Missense Mutation (SNP) | VAF 110/200 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV59770012; called by muse, mutect2, varscan2
- CELSR3 | c.2116G>A p.G706S | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51167330; called by muse, mutect2, varscan2
- CSPP1 | c.3180G>C p.K1060N (on ENST00000676605; = p.K1019N on NM_024790.6) | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV51593520; called by muse, mutect2, varscan2
- CYP3A43 | c.1026+1G>T p.X342_splice | Splice Site (SNP) | VAF 88/198 reads (44%) | catalogued as COSV55938461; called by muse, mutect2, varscan2
- DENND2D | c.218C>A p.P73H | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62960269; called by muse, mutect2, varscan2
- DLGAP4 | c.327G>C p.E109D | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.956); catalogued as COSV59424228; called by muse, mutect2, varscan2
- ERBB3 | c.1312G>A p.V438I | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57264680; called by muse, mutect2, varscan2
- EXOC4 | c.1736G>A p.S579N | Missense Mutation (SNP) | VAF 119/230 reads (52%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.972); catalogued as rs763566158, COSV54125618; called by muse, mutect2, varscan2
- FAHD2B | c.402C>G p.S134R | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV99738077; called by mutect2, varscan2
- FAR2 | c.365+1G>C p.X122_splice | Splice Site (SNP) | VAF 25/172 reads (15%) | catalogued as COSV99479118; called by muse, mutect2, varscan2
- FLG2 | c.3614T>A p.F1205Y | Missense Mutation (SNP) | VAF 40/252 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV101165890; called by muse, mutect2, varscan2
- FLG2 | c.1328A>T p.E443V | Missense Mutation (SNP) | VAF 110/334 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.113); catalogued as COSV66174120; called by muse, mutect2, varscan2
- HAO1 | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs148371109; called by muse, mutect2, varscan2
- HAUS1 | c.826A>T p.M276L | Missense Mutation (SNP) | VAF 89/193 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs777640499, COSV56364275; called by muse, mutect2, varscan2
- HEPACAM2 | c.1273A>T p.R425W (on ENST00000394468 / NM_001039372.4; = p.R413W on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/167 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV59063081; called by muse, mutect2
- HIPK2 | c.2315C>T p.T772I | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV61233369; called by muse, mutect2, varscan2
- HIPK3 | c.1292G>T p.R431I | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV57560936; called by muse, mutect2, varscan2
- HIPK3 | c.1293A>T p.R431S | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100305805; called by muse, mutect2, varscan2
- HRNR | c.5878C>A p.Q1960K | Missense Mutation (SNP) | VAF 24/282 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as COSV64264357; called by muse, mutect2
- INHA | c.872G>C p.C291S | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54712616, COSV54730718, COSV99217542; called by muse, mutect2, varscan2
- KAT6B | c.4853G>T p.S1618I | Missense Mutation (SNP) | VAF 61/215 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as COSV54755802; called by muse, mutect2, varscan2
- MAP3K19 | c.610A>G p.S204G | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as COSV59642677; called by muse, mutect2, varscan2
- MCAT | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV51793859; called by muse, mutect2, varscan2
- NID2 | c.229-1G>C p.X77_splice | Splice Site (SNP) | VAF 6/10 reads (60%) | catalogued as COSV53503742; called by muse, mutect2, varscan2
- NOTCH4 | c.2925A>T p.Q975H | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.039); catalogued as COSV66684335; called by muse, mutect2, varscan2
- PCDH9 | c.3433C>T p.P1145S (on ENST00000377865 / NM_203487.3; = p.P1111S on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/157 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as COSV60592024; called by muse, mutect2, varscan2
- PDIA3 | c.762G>T p.L254F | Missense Mutation (SNP) | VAF 26/30 reads (87%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as COSV55858653; called by muse, mutect2, varscan2
- RB1 | c.2104C>A p.Q702K | Missense Mutation (SNP) | VAF 39/41 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM030513, CM127815, COSV57307527, COSV57329700; called by muse, mutect2, varscan2
- RIMS1 | c.3253C>A p.H1085N | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV53457278, COSV53488223; called by muse, mutect2, varscan2
- SLC36A2 | c.905G>T p.G302V | Missense Mutation (SNP) | VAF 74/80 reads (93%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV58865386; called by muse, mutect2, varscan2
- SLC38A1 | c.916A>G p.K306E | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV67065085; called by muse, mutect2, varscan2
- SNX19 | c.787G>T p.V263L | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV56289419; called by muse, mutect2, varscan2
- SPOCD1 | c.1735C>G p.P579A | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV57100528; called by muse, mutect2, varscan2
- STXBP5L | c.3363T>G p.S1121R | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV56537654; called by muse, mutect2, varscan2
- TTN | c.89184del p.V29729Sfs*26 (on ENST00000591111; = p.V22305Sfs*26 on NM_003319.4) | Frame Shift Del (DEL) | VAF 18/79 reads (23%) | catalogued as CD121849; called by mutect2, pindel, varscan2
- VWA3A | c.1889A>G p.Y630C | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55395477; called by muse, mutect2, varscan2
- ZAN | c.4880C>G p.A1627G | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV100769747; called by muse, mutect2, varscan2
- ZMYND15 | c.1650dup p.E551Rfs*33 (on ENST00000433935 / NM_001136046.3; = p.E512Rfs*33 on NM_032265.2) | Frame Shift Ins (INS) | VAF 5/52 reads (10%) | catalogued as rs1484755918; called by pindel, varscan2
- ZNF101 | c.1136G>T p.S379I | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV58910215; called by muse, mutect2, varscan2
- ACKR1 | c.367_380del p.T123Pfs*3 | Frame Shift Del (DEL) | VAF 12/53 reads (23%) | called by mutect2, pindel, varscan2
- BRCA1 | c.3793_3794dup p.N1265Kfs*4 | Frame Shift Ins (INS) | VAF 170/258 reads (66%) | called by mutect2, pindel, varscan2
- CRYGB | c.236_242del p.C79Sfs*11 | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | called by mutect2, pindel, varscan2
- FOXI1 | c.361C>A p.L121M | Missense Mutation (SNP) | VAF 12/13 reads (92%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- IGLV5-48 | c.118dup p.T40Nfs*12 | Frame Shift Ins (INS) | VAF 119/244 reads (49%) | called by mutect2, pindel, varscan2
- JOSD1 | c.191_206del p.S64* | Frame Shift Del (DEL) | VAF 20/52 reads (38%) | called by mutect2, pindel, varscan2
- KIF26B | c.2258+3_2258+6del p.X753_splice | Splice Site (DEL) | VAF 27/60 reads (45%) | called by pindel, varscan2
- SKIV2L | c.599-1del p.X200_splice | Splice Site (DEL) | VAF 30/64 reads (47%) | called by mutect2, pindel, varscan2
- CBY1 | c.72G>A p.L24= | Silent (SNP) | VAF 24/29 reads (83%) | catalogued as COSV53265010; called by muse, mutect2, varscan2
- ENAH | c.1204A>C p.R402= | Silent (SNP) | VAF 32/69 reads (46%) | catalogued as COSV52873620; called by muse, mutect2, varscan2
- FCRL1 | c.180C>T p.A60= | Silent (SNP) | VAF 53/137 reads (39%) | catalogued as COSV63827004; called by muse, mutect2, varscan2
- H2AC21 | c.303C>A p.V101= | Silent (SNP) | VAF 53/186 reads (28%) | catalogued as COSV58612361, COSV58613315; called by muse, mutect2, varscan2
- INVS | c.837G>A p.K279= | Silent (SNP) | VAF 125/139 reads (90%) | catalogued as COSV52451148; called by muse, mutect2, varscan2
- IQGAP3 | c.1461C>G p.A487= | Silent (SNP) | VAF 142/256 reads (55%) | catalogued as COSV63255059; called by muse, mutect2, varscan2
- KARS1 | c.1494G>A p.A498= | Silent (SNP) | VAF 51/59 reads (86%) | catalogued as rs374568114; called by muse, mutect2, varscan2
- LATS1 | c.1986A>G p.K662= | Silent (SNP) | VAF 11/12 reads (92%) | catalogued as COSV53600967; called by muse, mutect2, varscan2
- MOV10 | c.672G>A p.S224= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs138014327; called by muse, mutect2, varscan2
- OR5B21 | c.411T>C p.G137= | Silent (SNP) | VAF 105/259 reads (41%) | catalogued as rs1270716499, COSV64482327; called by muse, mutect2, varscan2
- SCN1A | c.1770C>T p.F590= | Silent (SNP) | VAF 40/101 reads (40%) | catalogued as rs146520391; ClinVar: likely benign; called by muse, mutect2, varscan2
- WDR45B | c.888G>T p.P296= | Silent (SNP) | VAF 53/56 reads (95%) | catalogued as COSV66408862, COSV66409398; called by muse, mutect2, varscan2
- RALGAPA1 | c.*98A>G | 3'UTR (SNP) | VAF 17/21 reads (81%) | catalogued as rs769817636, COSV51892914; called by muse, mutect2, varscan2
